TARGET case TARGET-30-PANXJL — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e40c2997-8ab1-5ced-ae7f-bb00e578a06a

Demographics
Sex at birth: male; Age at index: 15 years; Vital status: Alive.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; ICD-10 code: C77.5; Tissue or organ of origin: Pelvic lymph nodes; Classification of tumor: primary; Age at diagnosis: 15.7 years (5,734 days); Year of diagnosis: 2005; Days to last follow up: 431 days (1.2 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 431 days (1.2 years); Event-free: no event (relapse, second malignancy or death) recorded through day 431; Year of follow up: 2006.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PANXJL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PANXJL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 431
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.24
- Histology: Unfavorable
- MKI: Low
- Diagnostic Category: Ganglioneuroblastoma, nodular
- ICDO Description: Pelvic lymph nodes Hypogastric lymph node Iliac lymph node Inferior epigastric lymph node Intrapelvic lymph node Obturator lymph node Paracervical lymph node Parametrial lymph node Presymphysial lymph node Sacral lymph node
